Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1KY, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1KY-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure: 1
DOB: [REDACTED] Date of Receipt: [REDACTED]
Physician: [REDACTED]
CC: [REDACTED]

....

108-0-3
dedifferentiated liposarcoma 8858/3
Site: Retroperitoneum C48.0
2/21/11
lw

Specimens Submitted:

- 1: SP: Normal psoas muscle
2: SP: Radical resection of right retroperitoneal sarcoma, right colectomy,
right nephrectomy, right adrenalectomy

DIAGNOSIS:

1. SKELETAL MUSCLE, PSOAS; EXCISION:
- SKELETAL MUSCLE INVOLVED BY SCLEROSING TYPE WELL-DIFFERENTIATED LIPOSARCOMA.
2. SOFT TISSUE, RIGHT COLON, RIGHT KIDNEY, RIGHT ADRENAL GLAND;
RADICAL RESECTION, RIGHT HEMICOLECTOMY, NEPHRECTOMY, ADRENALECTOMY:
- HIGH GRADE DEDIFFERENTIATED LIPOSARCOMA, WITH LARGE AREAS OF NECROSIS.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES AND HAS A MALIGNANT FIBROUS HISTIOCYTOMA- LIKE GROWTH PATTERN.
- TUMOR MEASURES 39.5 x 24.5 x 13.0 CM.
- TUMOR IS ADHERENT TO THE KIDNEY CAPSULE AND INVOLVES THE COLONIC SUBSEROSA.
- TUMOR EXTENDS TO UNDESIGNATED INKED MARGINS.
- UNREMARKABLE RENAL AND ADRENAL PARENCHYMA.
- UNREMARKABLE URETER.
- COLONIC AND SMALL INTESTINAL MARGINS ARE NEGATIVE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "normal psoas muscle," and consists of a 6.6 x 1.6 x 1.1 cm fragment of skeletal muscle. Portions of

** Continued on next page **

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: Gastric & Mixed Tumo

----- Page 2 of 3

the specimen are submitted for TPS. The remaining specimen is entirely submitted.

Summary of sections:

U- undesignated

2. The specimen is received fresh, labeled "radical resection of right retroperitoneal sarcoma, right colectomy, right nephrectomy, right adrenalectomy", and consists of a 39.5 x 24.5 x 13.0 cm soft tissue mass which consists of a 31.0 x 21.0 x 13.0 cm firm yellow-white lobulated tumor which is continuous with a 24.5 x 22.5 x 6.2 cm lobulated soft yellow tumor. The tumor mass is covered with a thin serosal membrane. Sectioning of the firm tumor show a lobulated, solid cut surface. Sectioning of the softer tumor shows ill-defined areas of lobulated fat. There is a focal area of disruption within the tumor measuring 12.8 x 5.5 cm. This area is hemorrhagic and necrotic. There is also a 17.0 x 8.5 cm unoriented segment of colon, whose mesentery is adherent to the tumor. The colon wall and mucosa are uninvolved. The tumor also encases a 11.3 x 5.8 cm kidney with a 17.5 cm ureter embedded within the tumor. The perinephric fat is pale yellow and smooth, and focally adherent to the kidney. Superior to the kidney and also embedded in fat is a 2.8 x 1.7 x 0.3 cm adrenal gland. Portions of the tumor are submitted for TPS. Representative sections are submitted.

Summary of sections:

CM- colonic margins

C- representative colon

UVM- ureterovascular margin

K- kidney

AD- adrenal gland

TDD- tumor, dedifferentiated areas

RF-renal fat

DT- disrupted tumor

T- tumor

Summary of Sections:

Part 1: SP: Normal psoas muscle

Block	Sect.	Site	PCs
3		U	6

Part 2: SP: Radical resection of right retroperitoneal sarcoma, right colectomy, right nephrectomy, right adrenalectomy

Block	Sect.	Site	PCs
1		AD	1
1		C	1
2		CM	4
2		DT	4

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service: Gastric & Mixed Tumo

Page 3 of 3

2	K	2
2	RF	2
5	T	10
10	TDD	20
1	UVM	3

**** End of Report ****

Source: NCI Genomic Data Commons file 4502d32b-ccf6-48af-8898-b810afd233b8 (TCGA-DX-A1KY.EEBAA43A-A941-460B-8B99-BD1BE1DAC577.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).